Somatic mutation profile of tumor specimen TCGA-G3-A5SI-01A (aliquot TCGA-G3-A5SI-01A-31D-A27I-10) from TCGA case TCGA-G3-A5SI, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 44.2 years (16,126 days).
Specimen TCGA-G3-A5SI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d21f9ad-bcaf-4acb-b697-90a16bc32a54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A5SI-10A (Blood Derived Normal), aliquot TCGA-G3-A5SI-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a35bceb-bc60-4870-ae64-f8334bb9276c

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 16, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.2400C>A p.Y800* | Nonsense Mutation (SNP) | VAF 45/112 reads (40%) | catalogued as COSV52710884; called by muse, mutect2, varscan2
- CACNA1H | c.4798T>C p.Y1600H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV62004393; called by muse, mutect2, varscan2
- CATSPER1 | c.1988T>C p.L663P | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV56413632; called by muse, mutect2, varscan2
- CERS4 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.48); catalogued as rs749213804, COSV52170591; called by muse, mutect2
- CKB | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62379722; called by muse, mutect2, varscan2
- CLOCK | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV59405001; called by muse, mutect2, varscan2
- GLI3 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67895147; called by muse, mutect2, varscan2
- GPR84 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV57209296, COSV57209477; called by muse, mutect2
- IGDCC4 | c.2767A>T p.M923L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV61539382; called by muse, mutect2, varscan2
- KHNYN | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV52163651; called by muse, mutect2
- OGN | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746882470, COSV52761959; called by muse, mutect2, varscan2
- PCBP3 | c.570C>A p.C190* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV68410199; called by muse, mutect2, varscan2
- PCDH11Y | c.3985A>T p.R1329* | Nonsense Mutation (SNP) | VAF 206/225 reads (92%) | catalogued as COSV53092001; called by muse, mutect2, varscan2
- PTPN13 | c.1151G>T p.R384I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV57418016; called by muse, mutect2, varscan2
- TAS2R3 | c.135C>G p.D45E | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56092885; called by muse, mutect2
- TMEM161A | c.86G>C p.R29P | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143085909, COSV50778080; called by muse, mutect2, varscan2
- TPX2 | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55922971; called by muse, mutect2, varscan2
- WT1 | c.1267T>C p.S423P | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV60084119; called by muse, mutect2, varscan2
- ZNF263 | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.286); catalogued as rs1167040483, COSV54598172; called by muse, mutect2, varscan2
- ANXA6 | c.1847del p.G616Afs*7 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- DTNA | c.1106del p.K369Rfs*5 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- PTPRT | c.3682_3683dup p.S1229Pfs*9 | Frame Shift Ins (INS) | VAF 56/140 reads (40%) | called by mutect2, pindel, varscan2
- RB1 | c.1346dup p.V450Sfs*13 | Frame Shift Ins (INS) | VAF 17/28 reads (61%) | called by mutect2, pindel, varscan2
- UGT2B4 | c.-1_22del | Translation Start Site (DEL) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- ABI3 | c.843A>T p.P281= | Silent (SNP) | VAF 5/106 reads (5%) | catalogued as COSV99865101; called by muse, mutect2
- APEH | c.1479C>T p.S493= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as COSV56536910; called by muse, mutect2, varscan2
- CFAP91 | c.135T>C p.F45= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV56344936; called by muse, mutect2, varscan2
- CWC22 | c.1881C>T p.A627= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs1379374023, COSV55432668; called by muse, mutect2, varscan2
- DEK | c.726G>A p.E242= | Silent (SNP) | VAF 8/111 reads (7%) | catalogued as rs1021251992, COSV55239835; called by muse, mutect2
- KCNQ3 | c.2154G>C p.V718= | Silent (SNP) | VAF 82/279 reads (29%) | catalogued as COSV66482548; called by muse, mutect2, varscan2
- MTREX | c.492A>C p.S164= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV57930330; called by muse, mutect2, varscan2
- SLC25A37 | c.741C>T p.L247= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs769234541, COSV51563780; called by muse, mutect2, varscan2
- SMG6 | c.375T>C p.A125= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as rs767969910, COSV53976708; called by muse, mutect2, varscan2
